Somatic mutation profile of tumor specimen TCGA-AR-A252-01A (aliquot TCGA-AR-A252-01A-11D-A167-09) from TCGA case TCGA-AR-A252, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.0 years (18,611 days).
Specimen TCGA-AR-A252-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed64f13a-1fdb-45c3-8fa6-34f29dc66a01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A252-10A (Blood Derived Normal), aliquot TCGA-AR-A252-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfde695f-0a83-451e-88de-370187b8412d

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK10 | c.365A>G p.Q122R (on ENST00000353379 / NM_052988.5; = p.Q51R on NM_052987.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV57047311; called by muse, mutect2, varscan2
- DDR2 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752360996, COSV63369675; called by muse, mutect2, varscan2
- LPAR5 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as COSV61692903; called by muse, mutect2, varscan2
- MYH2 | c.4424C>T p.A1475V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as COSV55439951; called by muse, mutect2, varscan2
- SDK1 | c.5906G>A p.R1969Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as rs201132659, COSV67356570, COSV67366479; called by muse, mutect2
- ZKSCAN5 | c.2012T>C p.F671S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV100460297; called by muse, mutect2
- ZNF670 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV100829303; called by muse, mutect2
- GATA3 | c.1236dup p.S413Qfs*94 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.810T>C p.F270= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100567426; called by muse, mutect2
- TMF1 | c.3270A>G p.Q1090= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV68374488; called by muse, mutect2, varscan2
